Gene-level copy-number profile of tumor specimen TCGA-XF-A9T0-01A from TCGA case TCGA-XF-A9T0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.0 years (25,190 days).
Specimen TCGA-XF-A9T0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fc6bb612-fa20-4204-8aea-faf7e8307e79.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9T0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/46a45333-a256-46c5-8220-86b25dc5c1f9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 32; copy number 2: 9,327; copy number 3: 8,678; copy number 4: 31,104; copy number 5: 4,816; copy number 6: 3,082; copy number 7: 1,043; copy number 8: 693; copy number 9: 77; copy number 10: 208; copy number 11: 111; copy number 14: 1; copy number 15: 622.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9T0-01A-11D-A390-01): tumor purity 0.76, ploidy 3.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:88,577,880–88,578,201, 1 gene: RPL36AP10.
- chr4:184,334,292–184,382,416, 2 genes (within-gene range 0–2): LINC02363, LINC02362.
- chr14:42,362,983–42,703,655, 1 gene (within-gene range 0–2): AL442163.1.
- chr14:42,608,868–42,808,112, 3 genes: AL442163.2, AL442163.3, YWHAQP1.
- chr14:67,819,779–68,730,218, 7 genes (within-gene range 0–2): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6.
- chr16:78,872,739–78,899,644, 3 genes: AC136603.1, AC027279.4, AC027279.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,019 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:224,107,282–224,175,706, 3 genes, copy number 9: RN7SKP49, FBXO28, AC092809.3.
- chr1:224,179,641–224,179,767, 1 gene, copy number 9: SNORA72.
- chr4:5,051,480–7,068,064, 39 genes, copy number 10 (within-gene range 2–10): STK32B, Y_RNA, RN7SKP275, LINC01587, EVC2, EVC, CRMP1, C4orf50, MIR378D1, JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1, PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1.
- chr4:20,392,154–20,394,856, 1 gene, copy number 14: SLIT2-IT1.
- chr5:36,098,407–36,302,114, 7 genes, copy number 9 (within-gene range 6–9): LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L.
- chr6:20,212,087–20,500,276, 9 genes, copy number 9: AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA.
- chr6:43,370,026–46,652,830, 71 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr8:79,520,145–90,687,863, 168 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr8:90,646,420–90,670,929, 1 gene, copy number 10: AC106038.1.
- chr22:15,290,718–30,276,951, 719 genes, copy number 9–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
